Somatic mutation profile of tumor specimen TARGET-40-PARVXK-01A (aliquot TARGET-40-PARVXK-01A-01D) from TARGET case TARGET-40-PARVXK, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of upper limb, scapula and associated joints; Age at diagnosis: 4.5 years (1,646 days).
Specimen TARGET-40-PARVXK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 601f3c13-f3f2-4412-9d50-4a1bd8208c03.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PARVXK-10A (Blood Derived Normal), aliquot TARGET-40-PARVXK-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/552aa6dd-34f3-4134-a323-90acbdcb50cd

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MUC16 | c.16607G>A p.R5536Q | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs763953432, COSV67500275; called by mutect2, varscan2
- ZNF90 | c.1601C>A p.A534E | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs186928119, COSV69001934, COSV69002776; called by muse, mutect2
